Somatic mutation profile of tumor specimen TCGA-66-2785-01A (aliquot TCGA-66-2785-01A-01W-0877-08) from TCGA case TCGA-66-2785, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.1 years (23,772 days).
Specimen TCGA-66-2785-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78bcb09e-e4df-4739-86c3-8e3668178488.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2785-11A (Solid Tissue Normal), aliquot TCGA-66-2785-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3bd85e5-61fc-4551-b778-70a5598b6260

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KNSTRN | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as rs535842654; called by mutect2, varscan2
- ZZEF1 | c.7859G>T p.R2620L | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67559814; called by muse, mutect2
- AKIP1 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.011); called by muse, varscan2
- EXOC1 | c.161A>G p.K54R | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- PYGL | c.440C>A p.S147Y | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SGK1 | c.61A>G p.K21E | Missense Mutation (SNP) | VAF 14/478 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- TFRC | c.1301C>A p.S434* | Nonsense Mutation (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- TRAK1 | c.2527C>A p.L843I | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRIML1 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.67); called by muse, mutect2
- DOP1B | c.1458G>T p.L486= | Silent (SNP) | VAF 7/73 reads (10%) | called by muse, mutect2
- PALM | c.432C>A p.G144= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, varscan2
- SLC22A18 | c.42C>T p.P14= | Silent (SNP) | VAF 13/17 reads (76%) | catalogued as rs748975421, COSV100388985; called by muse, mutect2
- SP1 | c.1290C>A p.I430= (on ENST00000327443 / NM_138473.3; = p.I423= on NM_003109.1) | Silent (SNP) | VAF 13/150 reads (9%) | catalogued as rs947944422; called by muse, mutect2
